Somatic mutation profile of tumor specimen TCGA-19-5959-01A (aliquot TCGA-19-5959-01A-11D-1696-08) from TCGA case TCGA-19-5959, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 77.9 years (28,449 days).
Specimen TCGA-19-5959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eb5c816-675d-48ee-a0b8-aa68c626c065.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5959-10A (Blood Derived Normal), aliquot TCGA-19-5959-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d651d40-d8f4-453d-b69d-6d7acaef57d3

The open-access MAF lists 90 somatic variants for this specimen: 62 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Nonstop Mutation 1, Intron 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs575011573, COSV51992777; called by muse, mutect2, varscan2
- AIFM1 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54854017; called by muse, mutect2, varscan2
- AK8 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 100/258 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375829164, COSV53752592; called by muse, mutect2, varscan2
- ARHGEF40 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV53880889; called by muse, mutect2, varscan2
- ATCAY | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as rs373780288, COSV56654866; called by muse, mutect2, varscan2
- BACH2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs762984505, COSV57594485; called by muse, mutect2, varscan2
- C10orf53 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs769258153, COSV65107768; called by muse, mutect2, varscan2
- CACNA1B | c.1906A>G p.N636D | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as COSV53128519; called by muse, mutect2, varscan2
- CCDC88A | c.1652_1653del p.R551Tfs*3 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs1376116733; called by pindel, varscan2
- CD1D | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs772663580, COSV63809117; called by muse, mutect2, varscan2
- CDH13 | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303332993, COSV51817788; called by muse, mutect2, varscan2
- CDH18 | c.1513-1G>C p.X505_splice | Splice Site (SNP) | VAF 32/62 reads (52%) | catalogued as COSV56926793; called by muse, mutect2, varscan2
- CHGB | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs144051265; called by muse, mutect2, varscan2
- CIP2A | c.2034G>T p.M678I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV55419099; called by muse, mutect2, varscan2
- CNTNAP2 | c.1054A>G p.R352G | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV62189348; called by muse, mutect2, varscan2
- CNTNAP4 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs148969138; called by muse, mutect2, varscan2
- CRNN | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200128647, COSV55122292; called by muse, mutect2, varscan2
- DCC | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59106073; called by muse, mutect2, varscan2
- DNAH1 | c.12320G>C p.G4107A | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56235026; called by muse, mutect2
- DOCK6 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs765129469, COSV53915772; called by muse, mutect2, varscan2
- DPEP3 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs377446311; called by muse, mutect2, varscan2
- EEF1A1 | c.296T>C p.I99T | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV58549819; called by muse, mutect2, varscan2
- FAM155B | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52936358; called by muse, varscan2
- FAM184A | c.2189C>T p.T730M | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs773464428, COSV58851698; called by muse, mutect2, varscan2
- FBLN2 | c.2510A>G p.Q837R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs752000409, COSV55485603, COSV99852237; called by muse, varscan2
- FPR2 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1331114419, COSV60671798, COSV60672438; called by muse, mutect2, varscan2
- GNPTG | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs139997459, CM163768, COSV50189821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN3 | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV62085236; called by muse, mutect2, varscan2
- HIF3A | c.1496A>G p.D499G (on ENST00000377670 / NM_152795.4; = p.D430G on NM_022462.4) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52199371; called by muse, mutect2, varscan2
- IL18RAP | c.251G>T p.W84L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51826421; called by muse, mutect2, varscan2
- ITGAM | c.2534G>A p.R845H (on ENST00000648685 / NM_001145808.2; = p.R844H on NM_000632.4) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs766088000, COSV54934811; called by muse, mutect2, varscan2
- MFF | c.118A>T p.T40S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV58825767; called by muse, mutect2, varscan2
- NEU4 | c.26G>A p.R9Q (on ENST00000391969 / NM_001167602.3; = p.R21Q on NM_080741.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs138212045; called by muse, mutect2, varscan2
- OAS1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1021340095, COSV52534554, COSV52536141; called by muse, mutect2, varscan2
- OR10H5 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV58278262; called by muse, mutect2, varscan2
- OR5A1 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV57376084, COSV57376244; called by muse, mutect2, varscan2
- OR8H3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs780954788, COSV57909304; called by muse, mutect2, varscan2
- OTOGL | c.2666G>C p.C889S (on ENST00000547103; = p.C880S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101509040; called by muse, mutect2, varscan2
- OVOL1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs547964049, COSV60119935; called by muse, mutect2, varscan2
- PCDHA7 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.341); catalogued as rs781842437, COSV65344578; called by muse, mutect2, varscan2
- PCNT | c.7901T>C p.V2634A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV64028981; called by muse, mutect2
- PRG4 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201785504, COSV63355674, COSV63356193; called by muse, mutect2, varscan2
- RELN | c.5059T>C p.S1687P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59005852; called by muse, mutect2, varscan2
- SERPINC1 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as rs745583962, COSV62929176, COSV62929598; called by muse, mutect2, varscan2
- SLC6A5 | c.1033A>T p.T345S | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV54227568; called by muse, mutect2, varscan2
- SRPK3 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54207975; called by muse, mutect2, varscan2
- STOX1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 42/56 reads (75%) | catalogued as COSV53815269; called by muse, mutect2, varscan2
- TEX15 | c.5362C>T p.R1788* (on ENST00000256246; = p.R2171* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 25/49 reads (51%) | catalogued as rs760122658, COSV56347485; called by muse, mutect2, varscan2
- TEX47 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs774856236, COSV51879143, COSV99787186; called by muse, mutect2, varscan2
- TMPRSS11F | c.751T>C p.W251R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62466871; called by muse, mutect2, varscan2
- TNFAIP1 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56876835; called by muse, mutect2, varscan2
- TTN | c.64028C>T p.A21343V (on ENST00000591111; = p.A13919V on NM_003319.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | PolyPhen benign (0.329); catalogued as COSV60105100; called by muse, mutect2, varscan2
- TTYH3 | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51860894; called by muse, mutect2, varscan2
- TXK | c.1582T>A p.*528Rext*37 | Nonstop Mutation (SNP) | VAF 75/170 reads (44%) | catalogued as COSV51916104; called by muse, mutect2, varscan2
- UGT1A10 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.258); catalogued as rs145610800; called by muse, mutect2, varscan2
- UGT3A2 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs545963580, COSV56930955; called by muse, mutect2, varscan2
- ZNF71 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV60148189; called by muse, mutect2, varscan2
- ZRSR2 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57065153; called by muse, mutect2, varscan2
- HUWE1 | c.6996del p.Q2333Sfs*19 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- IGHG1 | c.54_65del p.S19_T22del | In Frame Del (DEL) | VAF 3/33 reads (9%) | called by mutect2*, pindel
- PTEN | c.294del p.E99Nfs*14 | Frame Shift Del (DEL) | VAF 44/78 reads (56%) | called by mutect2, pindel, varscan2
- SCARB2 | c.276-1_278del p.X92_splice | Splice Site (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.5910C>T p.D1970= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as rs760543724, COSV54949082; called by muse, mutect2, varscan2
- ARRB1 | c.1083G>A p.P361= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs760045129, COSV63575782; called by muse, mutect2, varscan2
- CDH9 | c.1989C>T p.G663= | Silent (SNP) | VAF 71/168 reads (42%) | catalogued as rs202002897, COSV50251548, COSV50470538; called by muse, mutect2, varscan2
- CFAP161 | c.315C>T p.D105= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs371138907; called by muse, mutect2, varscan2
- CSPG4 | c.3315G>A p.L1105= | Silent (SNP) | VAF 55/112 reads (49%) | catalogued as COSV57896092; called by muse, mutect2, varscan2
- CTSV | c.381G>A p.T127= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs763498015, COSV52344923; called by muse, mutect2, varscan2
- DRD1 | c.711C>T p.H237= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs777655360, COSV67104736; called by muse, mutect2, varscan2
- FTHL17 | c.135C>T p.D45= | Silent (SNP) | VAF 46/110 reads (42%) | catalogued as COSV63266352; called by muse, mutect2, varscan2
- GRIN2B | c.3954C>G p.A1318= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs1295379373, COSV74206123; called by muse, mutect2, varscan2
- HAS2 | c.138T>C p.F46= | Silent (SNP) | VAF 54/161 reads (34%) | catalogued as COSV58264420; called by muse, mutect2, varscan2
- HIVEP3 | c.2439G>A p.E813= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV56016366; called by muse, mutect2, varscan2
- IGHV2-26 | c.114G>A p.T38= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs782328202; called by muse, mutect2, varscan2
- ITGA11 | c.873C>T p.N291= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs776791415, COSV59875003; called by muse, mutect2, varscan2
- NT5DC2 | c.180C>T p.N60= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs148646310; called by muse, mutect2, varscan2
- OBSCN | c.15192G>A p.A5064= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs753852976, COSV52780785; called by muse, mutect2, varscan2
- OR4K15 | c.282C>T p.D94= (on ENST00000305051; = p.D70= on NM_001005486.1) | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as rs774065100, COSV59300427; called by muse, mutect2, varscan2
- PPP1R32 | c.84C>T p.Y28= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1385213019, COSV58545026; called by muse, mutect2, varscan2
- RELN | c.1092C>T p.L364= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as rs142192165; ClinVar: likely benign; called by muse, mutect2, varscan2
- REPIN1 | c.1512G>A p.S504= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs749777134, COSV68292428; called by muse, mutect2, varscan2
- RTP3 | c.603C>T p.Y201= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as rs547846654, COSV56123798, COSV99947010; called by muse, mutect2, varscan2
- SKI | c.1164G>A p.A388= | Silent (SNP) | VAF 86/196 reads (44%) | catalogued as rs780171614, COSV66013613; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNTA1 | c.939G>A p.L313= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54129373; called by muse, mutect2, varscan2
- SRMS | c.192G>A p.A64= | Silent (SNP) | VAF 147/555 reads (26%) | catalogued as rs140773907; called by muse, mutect2, varscan2
- TACSTD2 | c.969G>A p.L323= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV64667124; called by muse, mutect2, varscan2
- TMEM266 | c.93C>T p.D31= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs1251964044, COSV66379683; called by muse, mutect2, varscan2
- TNFSF9 | c.624C>T p.A208= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs201323170, COSV55538442; called by muse, mutect2, varscan2
- AMFR | c.*722C>G | 3'UTR (SNP) | VAF 12/29 reads (41%) | catalogued as rs1348460207, COSV51924960, COSV99315711; called by muse, varscan2
- RIMS2 | c.1692+235G>C | Intron (SNP) | VAF 29/61 reads (48%) | catalogued as COSV51656771, COSV99163821; called by muse, mutect2, varscan2
